Somatic mutation profile of tumor specimen TCGA-EB-A3Y6-01A (aliquot TCGA-EB-A3Y6-01A-21D-A23B-08) from TCGA case TCGA-EB-A3Y6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 56.4 years (20,605 days).
Specimen TCGA-EB-A3Y6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90c33134-03b1-4d57-a3e5-4b263cc21423.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A3Y6-10A (Blood Derived Normal), aliquot TCGA-EB-A3Y6-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/323f6c0b-967d-4c1a-acc2-7b27a71b3dab

The open-access MAF lists 722 somatic variants for this specimen: 475 protein-altering or splice-affecting, 228 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 438, Silent 228, Nonsense Mutation 21, Splice Site 9, Intron 7, Splice Region 5, 3'UTR 4, RNA 4, 3'Flank 2, Frame Shift Del 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL3A1 | c.3329G>A p.G1110E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794728055, COSV58596135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DDX28 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 31/68 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV60106169; called by muse, mutect2, varscan2
- F13A1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 68/186 reads (37%) | catalogued as rs121913065, CM930201, COSV53553799, COSV53554927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDE6A | c.2275-1G>A p.X759_splice | Splice Site (SNP) | VAF 5/74 reads (7%) | catalogued as rs1428612396, COSV54931154; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.5645G>A p.R1882Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs794727444, CM136053, CM145316, COSV51836760, COSV51839118; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- THSD7B | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55688858; called by muse, mutect2, varscan2
- ABCA13 | c.7558G>A p.D2520N | Missense Mutation (SNP) | VAF 90/270 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.081); catalogued as COSV71282907, COSV71294006; called by muse, mutect2, varscan2
- ABCA13 | c.10075C>T p.Q3359* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as rs758788937, COSV71294007; called by muse, mutect2, varscan2
- ABCA5 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1280114367, COSV67018995; called by muse, mutect2, varscan2
- ACAN | c.4415C>T p.S1472F | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV61368868; called by muse, mutect2, varscan2
- ACSBG2 | c.971G>T p.W324L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53127675; called by muse, mutect2, varscan2
- ACTL6B | c.1052A>G p.N351S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867424780, COSV50518426; called by muse, mutect2, varscan2
- ACTL6B | c.890A>G p.E297G | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50518493; called by muse, mutect2, varscan2
- ADAM29 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV63667937; called by muse, mutect2, varscan2
- ADAMTS2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755997172, COSV51072403; called by muse, mutect2, varscan2
- ADAMTS20 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV67128809, COSV67131706; called by muse, mutect2, varscan2
- ADAMTSL2 | c.90+1G>A p.X30_splice | Splice Site (SNP) | VAF 20/70 reads (29%) | catalogued as COSV63206189; called by muse, mutect2, varscan2
- ADCY5 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs79462429, COSV59204173; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 114/344 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781547594, COSV58446584; called by muse, mutect2, varscan2
- ADGRG3 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV59652601; called by muse, mutect2, varscan2
- ADGRG4 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54962955; called by muse, mutect2, varscan2
- ADGRV1 | c.15407C>T p.S5136F | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs867467575, COSV67987841, COSV67994326; called by muse, mutect2
- ADH1A | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV52924289; called by muse, mutect2, varscan2
- AHNAK | c.5279C>T p.P1760L | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57229518; called by muse, mutect2, varscan2
- AIFM3 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV58998497; called by muse, mutect2
- AKAP3 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs200943042, COSV57419632; called by muse, mutect2, varscan2
- AKAP9 | c.7777A>G p.K2593E (on ENST00000359028; = p.K2569E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1317191455, COSV62357431; called by muse, mutect2, varscan2
- AMBRA1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs868488160, COSV54062228; called by muse, mutect2, varscan2
- AMTN | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as rs1276900938, COSV59490180; called by muse, mutect2, varscan2
- AMY1C | c.879G>A p.K293= | Splice Region (SNP) | VAF 24/807 reads (3%) | catalogued as COSV64407220; called by muse, mutect2
- ANK3 | c.9832G>A p.E3278K | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as rs775646259, COSV55080204; called by muse, mutect2, varscan2
- ANKFN1 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs758080488, COSV59459393; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7562C>T p.A2521V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as rs1324668355, COSV51857828; called by muse, mutect2, varscan2
- ANKRD12 | c.5165C>T p.A1722V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV50841863; called by muse, mutect2, varscan2
- ANKRD12 | c.5692C>T p.P1898S | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV50847090; called by muse, mutect2, varscan2
- ANKRD30A | c.3148G>A p.E1050K (on ENST00000611781; = p.E994K on NM_052997.2) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1237785275, COSV64605238; called by muse, mutect2, varscan2
- ANKRD33 | c.193G>A p.G65R (on ENST00000340970 / NM_001304459.2; = p.G200R on NM_182608.4) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56608357; called by muse, mutect2, varscan2
- ANKRD7 | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV54556459; called by muse, mutect2, varscan2
- APCS | c.380G>A p.W127* | Nonsense Mutation (SNP) | VAF 22/127 reads (17%) | catalogued as rs775779605, COSV54819229; called by muse, mutect2, varscan2
- APOBEC1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57548361, COSV57548677; called by muse, varscan2
- APOH | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52774909; called by muse, mutect2, varscan2
- ARHGEF7 | c.1844C>T p.P615L (on ENST00000375741 / NM_001113511.2; = p.P437L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs373754333; called by muse, mutect2, varscan2
- ARMC4 | c.2299G>A p.D767N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV59471571; called by muse, mutect2, varscan2
- ARR3 | c.32A>T p.N11I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57205347; called by muse, mutect2, varscan2
- ASB16 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.136); catalogued as COSV53236414; called by muse, mutect2, varscan2
- ASCC1 | c.530G>A p.G177E (on ENST00000342444 / NM_001369085.1; = p.G149E on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.791); catalogued as COSV57728785; called by muse, mutect2, varscan2
- ASXL2 | c.2509G>A p.G837S | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.141); catalogued as COSV55467601; called by muse, mutect2, varscan2
- ATF7IP | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as COSV53773213; called by muse, mutect2
- ATP13A2 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV58703544; called by muse, mutect2, varscan2
- ATP13A4 | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.111); catalogued as rs1378732024, COSV55074962; called by muse, mutect2, varscan2
- ATP8B4 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); catalogued as COSV52723885; called by muse, mutect2
- ATP9B | c.2557C>T p.Q853* | Nonsense Mutation (SNP) | VAF 26/115 reads (23%) | catalogued as rs759598890, COSV100303531, COSV56960950; called by muse, mutect2, varscan2
- B3GNTL1 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV57953788; called by muse, mutect2, varscan2
- BAIAP2 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.125); catalogued as COSV100348668; called by muse, mutect2, varscan2
- BAIAP2 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs750986627, COSV100348674; called by muse, mutect2, varscan2
- BCL11B | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61739185; called by muse, mutect2
- BEGAIN | c.1372A>T p.K458* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV62070123; called by muse, mutect2, varscan2
- BEST1 | c.1014G>A p.W338* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV56446550; called by muse, mutect2
- BMPR1B | c.247-1G>A p.X83_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as COSV52781631, COSV99215357; called by muse, mutect2, varscan2
- BNIP1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV51572010; called by muse, mutect2, varscan2
- BOD1L1 | c.5809A>T p.T1937S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV50061018; called by muse, mutect2, varscan2
- BPIFB3 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100972403; called by muse, mutect2, varscan2
- BPIFB6 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as COSV62755354; called by muse, mutect2, varscan2
- BRINP2 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV64180106; called by muse, mutect2
- BRWD1 | c.2860A>G p.K954E | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV60902536; called by muse, mutect2, varscan2
- BSN | c.5081G>A p.R1694K | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as COSV56526906; called by muse, mutect2, varscan2
- BSN | c.11540G>A p.G3847E | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.112); catalogued as COSV56526915; called by muse, mutect2, varscan2
- BTN3A1 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV50025372; called by muse, mutect2, varscan2
- C6 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54708223; called by muse, mutect2, varscan2
- C7 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV57479052; called by muse, mutect2
- C7 | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as CM074721, COSV57480579; called by muse, mutect2, varscan2
- C8orf34 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as COSV57412556; called by muse, mutect2, varscan2
- CACNA2D1 | c.2369C>T p.S790L (on ENST00000356253 / NM_001366867.1; = p.S778L on NM_000722.4) | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.288); catalogued as rs202108848, COSV62373773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASP7 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775867698, COSV61883310; called by muse, mutect2, varscan2
- CASR | c.1870C>T p.R624C (on ENST00000490131; = p.R701C on NM_000388.4) | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as rs757302986, CD123761, COSV56141237; called by muse, mutect2, varscan2
- CCDC160 | c.740A>G p.K247R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV66251966; called by muse, mutect2
- CCDC174 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.296); catalogued as rs866411473, COSV53783586; called by muse, mutect2
- CCDC180 | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as rs765165990, COSV63835082; called by muse, mutect2, varscan2
- CCDC22 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV66052002; called by muse, mutect2, varscan2
- CD5L | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 167/318 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as rs765807105, COSV63820985, COSV63823341; called by muse, mutect2, varscan2
- CD96 | c.62-1G>A p.X21_splice | Splice Site (SNP) | VAF 36/147 reads (24%) | catalogued as COSV99343440; called by muse, mutect2, varscan2
- CD96 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99343443; called by muse, mutect2, varscan2
- CDCA7 | c.24G>A p.Q8= | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as COSV60721748; called by muse, mutect2, varscan2
- CDH23 | c.7217C>T p.S2406F | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV56488500; called by muse, mutect2, varscan2
- CEMIP2 | c.2792G>A p.G931E | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65485082; called by muse, mutect2, varscan2
- CEP126 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.22); catalogued as COSV54830433; called by muse, mutect2, varscan2
- CFAP47 | c.2692T>A p.F898I | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52891614; called by muse, mutect2, varscan2
- CHL1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV56595589; called by muse, mutect2, varscan2
- CHRNB1 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV53441149; called by muse, mutect2, varscan2
- CHST8 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99381507; called by muse, mutect2, varscan2
- CIT | c.4384G>A p.G1462S | Missense Mutation (SNP) | VAF 59/256 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV55882599; called by muse, mutect2, varscan2
- CLCN7 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as COSV51973735; called by muse, mutect2, varscan2
- CLEC3A | c.317C>T p.S106F (on ENST00000651443; = p.S97F on NM_005752.6) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV55221285, COSV55224170; called by muse, mutect2, varscan2
- CNGB1 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.012); catalogued as COSV51906812, COSV51907562; called by muse, mutect2, varscan2
- CNTRL | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.644); catalogued as COSV53044120, COSV53053369; called by muse, mutect2, varscan2
- COL11A1 | c.3910C>T p.P1304S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV62182089; called by muse, mutect2
- COL18A1 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV62707050; called by muse, mutect2, varscan2
- COL26A1 | c.1169C>T p.P390L (on ENST00000313669 / NM_001278563.3; = p.P388L on NM_133457.4) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs745364304, COSV100561968; called by muse, mutect2, varscan2
- COL2A1 | c.2890C>T p.P964S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV61531586, COSV61534086; called by muse, mutect2, varscan2
- COL4A3 | c.3755C>T p.A1252V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs761179248, COSV59257746; called by muse, mutect2, varscan2
- COL6A6 | c.4624C>T p.P1542S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV62036720; called by muse, mutect2, varscan2
- COL9A2 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV65608091; called by mutect2, varscan2
- COX6B2 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV58485154; called by muse, mutect2, varscan2
- CPM | c.1203T>G p.D401E | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs202163169, COSV58035870; called by muse, mutect2, varscan2
- CRB1 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 85/156 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV66332177; called by muse, mutect2, varscan2
- CSRNP2 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV50399875; called by muse, mutect2, varscan2
- CTNNA3 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1387982830, COSV65562404; called by muse, mutect2, varscan2
- CTSE | c.929C>T p.P310L (on ENST00000360218; = p.P305L on NM_001910.4) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV63061186, COSV63061850; called by muse, mutect2, varscan2
- CTSL | c.338A>C p.E113A | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV58247420; called by muse, mutect2, varscan2
- CYP2C9 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as COSV53251346; called by muse, mutect2, varscan2
- CYP3A4 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60504117; called by muse, mutect2
- CYP4A11 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV60225540; called by muse, mutect2, varscan2
- DACH1 | c.1810G>A p.G604S (on ENST00000619232 / NM_001366712.1; = p.G350S on NM_004392.6) | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.299); catalogued as rs866547493, COSV57518992; called by muse, mutect2, varscan2
- DAW1 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59368992; called by muse, mutect2, varscan2
- DCAF4L2 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs780634469, COSV60482216; called by muse, mutect2, varscan2
- DCST2 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV55054478; called by muse, mutect2, varscan2
- DDOST | c.1040C>T p.P347L (on ENST00000415136; = p.P330L on NM_005216.5) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100387399; called by muse, mutect2, varscan2
- DDOST | c.1039C>T p.P347S (on ENST00000415136; = p.P330S on NM_005216.5) | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100387400; called by muse, mutect2, varscan2
- DDX53 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs1353262448, COSV100029045, COSV60069952; called by muse, mutect2, varscan2
- DDX60 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV67099217; called by muse, mutect2, varscan2
- DENND1C | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs1202951012, COSV67375202; called by muse, mutect2, varscan2
- DENND4A | c.186T>A p.D62E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV71266972; called by muse, mutect2
- DENND5B | c.3353C>T p.T1118I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60908228; called by muse, mutect2, varscan2
- DEPDC1B | c.851A>C p.E284A | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV54013025; called by muse, mutect2, varscan2
- DIP2B | c.4621G>A p.D1541N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99999166; called by muse, mutect2, varscan2
- DISP1 | c.836A>G p.K279R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as COSV52664783; called by muse, mutect2
- DISP1 | c.3464C>T p.S1155F | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV52664791; called by muse, mutect2, varscan2
- DISP2 | c.3622C>T p.P1208S | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as COSV51141652; called by muse, mutect2, varscan2
- DKC1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV65730234; called by muse, mutect2, varscan2
- DLG3 | c.1184G>A p.G395D (on ENST00000374360 / NM_021120.4; = p.G58D on NM_020730.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV52086868; called by muse, mutect2, varscan2
- DLGAP3 | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52397461, COSV99332084; called by muse, mutect2, varscan2
- DLGAP4 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs371602287, COSV59414211, COSV59416040; called by muse, mutect2, varscan2
- DNAAF3 | c.1379C>A p.S460* (on ENST00000524407 / NM_001256715.2; = p.S507* on NM_178837.4) | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV61279411; called by muse, mutect2, varscan2
- DNASE1L3 | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.04); catalogued as COSV59156157; called by muse, mutect2, varscan2
- DOT1L | c.4370C>T p.S1457F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.576); catalogued as rs760426764, COSV67113278; called by muse, mutect2, varscan2
- DPY19L1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs991704032, COSV60583047; called by muse, mutect2
- DRD1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs867085762, COSV67105195; called by muse, mutect2, varscan2
- DSG3 | c.2762C>T p.S921F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV57129554, COSV99934576; called by muse, mutect2, varscan2
- DSP | c.6814C>T p.L2272F | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV65795762; called by muse, mutect2, varscan2
- DTD1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.203); catalogued as COSV66282060; called by muse, mutect2
- EHBP1L1 | c.1988T>C p.V663A | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58575010; called by muse, mutect2
- ELAPOR1 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1282407047, COSV64041245; called by muse, varscan2
- ELMO1 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs1296323394, COSV60323788; called by muse, mutect2, varscan2
- ELN | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52715289; called by muse, mutect2, varscan2
- EPB41L2 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.807); catalogued as COSV61353434, COSV61358916; called by muse, mutect2, varscan2
- ERICH3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58617846; called by muse, mutect2, varscan2
- EXPH5 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56207978; called by muse, mutect2, varscan2
- EXTL3 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.525); catalogued as rs1248841409, COSV55040409; called by muse, mutect2, varscan2
- EYA1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs371408686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM71D | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV61295136; called by muse, mutect2
- FANK1 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV64156765, COSV64157144; called by muse, mutect2, varscan2
- FAT2 | c.8005C>T p.P2669S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55818869, COSV55829025; called by muse, mutect2
- FAT4 | c.10990C>T p.P3664S | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV58707860; called by muse, mutect2, varscan2
- FBLN7 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs763280507, COSV55617310; called by muse, mutect2, varscan2
- FBXW12 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs137962592; called by muse, mutect2
- FCGR3A | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63459066; called by muse, mutect2, varscan2
- FGD6 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as COSV100676762; called by muse, varscan2
- FGD6 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.257); catalogued as COSV100676763; called by muse, varscan2
- FLG | c.7624G>A p.D2542N | Missense Mutation (SNP) | VAF 145/870 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs748676210, COSV64239916, COSV64241484; called by muse, mutect2, varscan2
- FLG | c.6715C>T p.R2239W | Missense Mutation (SNP) | VAF 42/728 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs767399613, COSV64237417; called by muse, mutect2
- FLG2 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 155/829 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV66173032; called by muse, mutect2, varscan2
- FLNB | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55894637, COSV55897250; called by muse, mutect2, varscan2
- FLNB | c.5474C>T p.S1825F | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1268036129, COSV55894654; called by muse, mutect2, varscan2
- FMN2 | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as rs757963399, COSV60452516; called by muse, mutect2, varscan2
- FRAS1 | c.11596G>A p.D3866N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.526); catalogued as COSV53645684; called by muse, mutect2, varscan2
- FRK | c.1305T>G p.S435R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV73384245; called by muse, mutect2, varscan2
- GAS7 | c.785C>T p.S262F (on ENST00000432992 / NM_201433.2; = p.S122F on NM_003644.3) | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as rs868671986, COSV100096685; called by muse, mutect2, varscan2
- GDF15 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as rs762192147, COSV53251298; called by muse, mutect2, varscan2
- GHDC | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs756053992, COSV100054897; called by muse, varscan2
- GINS1 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52466371; called by muse, mutect2, varscan2
- GK2 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs267600272, COSV62626492; called by muse, mutect2, varscan2
- GK2 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs267600273, COSV62626353; called by muse, mutect2, varscan2
- GLYATL1 | c.538G>A p.G180R (on ENST00000317391 / NM_001354699.1; = p.G211R on NM_080661.4) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV55611356; called by muse, mutect2, varscan2
- GPLD1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV57760988; called by muse, mutect2, varscan2
- GPR149 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs201040008; called by muse, mutect2, varscan2
- GRIA2 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52385092; called by muse, varscan2
- GRIA2 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52389699; called by muse, varscan2
- GRIK3 | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1228177910, COSV66146496; called by muse, mutect2, varscan2
- HECTD4 | c.7628C>T p.T2543I | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV66399617; called by muse, mutect2, varscan2
- HECW2 | c.4436G>T p.R1479L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs143511416, COSV53659825; called by muse, mutect2, varscan2
- HERPUD2 | c.340-1G>A p.X114_splice | Splice Site (SNP) | VAF 6/86 reads (7%) | catalogued as COSV60947245; called by muse, mutect2
- HEXA | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51508761; called by muse, mutect2, varscan2
- HMGCS2 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | catalogued as rs137852637, CM011367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HS6ST2 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as COSV63711338, COSV63711342, COSV63718069; called by muse, mutect2, varscan2
- ICE1 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV56831980; called by muse, mutect2, varscan2
- IDO1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV53713031; called by muse, mutect2
- IFNA21 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV66518951; called by muse, varscan2
- IGHV3-43 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as rs182650845; called by muse, mutect2, varscan2
- IL17RD | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV56339173; called by muse, mutect2, varscan2
- IL18RAP | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1267139477, COSV51829192; called by muse, mutect2, varscan2
- IL21R | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV61972504; called by muse, mutect2, varscan2
- IL36A | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV52083521, COSV52083806; called by muse, mutect2, varscan2
- IQCA1 | c.1769C>T p.T590I | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54512317; called by muse, mutect2, varscan2
- IQSEC3 | c.3266C>T p.T1089I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV58290714; called by muse, mutect2, varscan2
- IRX2 | c.657G>A p.G219= | Splice Region (SNP) | VAF 9/46 reads (20%) | catalogued as COSV57413640; called by muse, mutect2, varscan2
- IRX6 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV51862188, COSV99306540; called by muse, mutect2, varscan2
- ITGB4 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV52326441; called by muse, mutect2, varscan2
- ITGB5 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777396601, COSV56152913; called by muse, mutect2, varscan2
- KCNB1 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65570706; called by muse, mutect2
- KCNB2 | c.1060T>A p.F354I | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV73052895; called by muse, mutect2, varscan2
- KCNC2 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs898373321, COSV54362666, COSV54379208; called by muse, mutect2, varscan2
- KCNG4 | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV57585859; called by muse, mutect2, varscan2
- KCNH7 | c.2447C>T p.A816V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV59812869; called by muse, mutect2, varscan2
- KCNK1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV64038312; called by muse, mutect2, varscan2
- KIAA0232 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.104); catalogued as COSV56929315; called by muse, mutect2, varscan2
- KIAA1210 | c.4607C>T p.S1536F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as COSV68180047; called by muse, mutect2, varscan2
- KIAA1210 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs374027596, COSV68180062; called by muse, mutect2, varscan2
- KIAA1522 | c.1483C>T p.P495S (on ENST00000373480 / NM_001198972.2; = p.P554S on NM_020888.3) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs943978497, COSV53867824; called by muse, mutect2
- KIF3B | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.5); catalogued as rs1190754129, COSV65227095, COSV65229272; called by muse, mutect2, varscan2
- KIFAP3 | c.1559T>A p.F520Y | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.265); catalogued as COSV63037110; called by muse, mutect2, varscan2
- KLHL34 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV65279467; called by muse, mutect2, varscan2
- KRT10 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.945); catalogued as rs1441986571, COSV54091470; called by muse, mutect2, varscan2
- KRT222 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.332); catalogued as COSV67499146; called by muse, mutect2, varscan2
- KRT80 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs780236621, COSV57551514; called by muse, mutect2
- KRTAP10-3 | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV59979070; called by muse, mutect2, varscan2
- KRTAP5-3 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.998); catalogued as COSV68791210; called by muse, mutect2, varscan2
- LBR | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as COSV55291627; called by muse, mutect2, varscan2
- LGI2 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV66122269; called by muse, mutect2, varscan2
- LINGO2 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58064176; called by muse, mutect2, varscan2
- LRP2 | c.6284G>A p.R2095Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs769929318, COSV55542779; called by muse, mutect2, varscan2
- LRRC49 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV53015329; called by muse, mutect2, varscan2
- LTF | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51612005, COSV51612922; called by muse, mutect2, varscan2
- LVRN | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1262750808, COSV63498332; called by muse, mutect2, varscan2
- LZTS3 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61278968; called by muse, mutect2, varscan2
- MADD | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778568100, COSV60620183; called by muse, mutect2, varscan2
- MAGEB16 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV67874548; called by muse, mutect2
- MAGEC1 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1391378383, COSV53580940; called by muse, mutect2, varscan2
- MAGEC2 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV56001352; called by muse, mutect2, varscan2
- MAGI2 | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62689823; called by muse, mutect2, varscan2
- MAN1C1 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56048446; called by muse, mutect2, varscan2
- MAOA | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58643814; called by muse, mutect2, varscan2
- MAP2K3 | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 50/331 reads (15%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.956); catalogued as COSV57577093; called by muse, mutect2, varscan2
- MCOLN2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as rs1302535632, COSV52295902, COSV99393700; called by muse, mutect2
- MEIG1 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV65542868; called by muse, mutect2
- MFHAS1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.158); catalogued as rs994006753, COSV52286754; called by muse, mutect2, varscan2
- MGAT5B | c.1606C>T p.P536S (on ENST00000569840 / NM_001199172.2; = p.P534S on NM_144677.3) | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV56936440, COSV56937598; called by muse, mutect2, varscan2
- MMAA | c.940C>A p.R314S | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as COSV55579017, COSV55581285; called by muse, mutect2, varscan2
- MOCS1 | c.890T>G p.F297C | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57939921; called by muse, mutect2, varscan2
- MOGAT3 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs769734697, COSV56176992; called by muse, mutect2, varscan2
- MPDZ | c.5194C>T p.P1732S | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as COSV59924306; called by muse, mutect2, varscan2
- MRC2 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763886887, COSV57644370; called by mutect2, varscan2
- MROH2B | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1374058264, COSV68185215; called by muse, mutect2, varscan2
- MRPS31 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.96); catalogued as rs1386449506, COSV60268915; called by muse, mutect2, varscan2
- MTBP | c.2033T>A p.L678H | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59966351; called by muse, mutect2, varscan2
- MTDH | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV60346490; called by muse, mutect2, varscan2
- MUC16 | c.33809C>T p.P11270L | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV67491883; called by muse, mutect2
- MXRA5 | c.6308C>T p.P2103L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54249623; called by muse, mutect2, varscan2
- MYLK | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as rs111422191, COSV60622100; called by muse, mutect2, varscan2
- MYLK2 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767857271, COSV65659847; called by muse, mutect2, varscan2
- MYO5B | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV99546054; called by muse, mutect2, varscan2
- MYO5C | c.4201T>A p.F1401I | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV55911813; called by muse, mutect2, varscan2
- NAT8L | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.417); catalogued as COSV59052180; called by muse, mutect2, varscan2
- NAV2 | c.5080C>T p.R1694C (on ENST00000396087 / NM_001244963.2; = p.R1638C on NM_145117.5) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs746641901, COSV60665111; called by muse, mutect2, varscan2
- NBEA | c.8591C>T p.S2864L | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV59816551; called by muse, mutect2, varscan2
- NDST4 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs765437158, COSV52109844, COSV52125800; called by muse, mutect2, varscan2
- NDST4 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 16/26 reads (62%) | catalogued as rs749271707, COSV52112958; called by muse, mutect2, varscan2
- NEK5 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as COSV62881899, COSV62882074; called by muse, mutect2, varscan2
- NEO1 | c.1194G>C p.L398F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56077974; called by muse, mutect2, varscan2
- NEO1 | c.2680C>T p.R894* | Nonsense Mutation (SNP) | VAF 25/104 reads (24%) | catalogued as COSV99981319; called by muse, mutect2, varscan2
- NFIX | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62180862; called by muse, mutect2, varscan2
- NHS | c.2465G>A p.R822K | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV66282208; called by muse, mutect2, varscan2
- NIM1K | c.1058A>T p.E353V | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV58145630; called by muse, mutect2, varscan2
- NINL | c.2958G>A p.W986* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as rs764539711, COSV53999373, COSV54008633; called by muse, mutect2, varscan2
- NLGN4X | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.899); catalogued as COSV52029040, COSV99320313; called by muse, mutect2, varscan2
- NLRP2 | c.2098G>A p.D700N | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54757150; called by muse, mutect2, varscan2
- NPAP1 | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.031); catalogued as COSV61510859; called by muse, mutect2, varscan2
- NPC1L1 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.261); catalogued as COSV56930107; called by muse, mutect2, varscan2
- NPIPB15 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); catalogued as COSV101466054, COSV70438492; called by muse, mutect2, varscan2
- NR3C2 | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV60999624; called by muse, mutect2
- NRXN1 | c.571T>G p.S191A | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV68045742; called by muse, mutect2
- NTRK1 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as rs760131903, COSV62328538; called by muse, mutect2, varscan2
- NTRK1 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV62324754; called by muse, mutect2
- NUFIP2 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1462900503, COSV56605855; called by muse, mutect2, varscan2
- NUTM2G | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.382); catalogued as COSV63617848; called by muse, mutect2, varscan2
- OR10A6 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as rs267603211, COSV59164785; called by muse, mutect2, varscan2
- OR10X1 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV63767979; called by muse, mutect2, varscan2
- OR11A1 | c.796G>T p.V266F | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV65821378; called by muse, mutect2, varscan2
- OR13C2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73377660; called by muse, mutect2, varscan2
- OR1E1 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV100491898, COSV59459732; called by muse, mutect2, varscan2
- OR1L3 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs766370067, COSV59169264; called by muse, mutect2
- OR2A2 | c.421A>T p.T141S | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV68872525; called by muse, mutect2, varscan2
- OR2G6 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 83/154 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV58575799; called by muse, mutect2, varscan2
- OR2L8 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 95/732 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV61728268; called by muse, mutect2, varscan2
- OR2W3 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV64455951, COSV64456750; called by muse, mutect2
- OR4K17 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV59649073; called by muse, mutect2, varscan2
- OR4K2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV53851578; called by muse, mutect2
- OR52E8 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs781170349, COSV66205287; called by muse, mutect2, varscan2
- OR52E8 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV66212166; called by muse, mutect2
- OR5K3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.694); catalogued as rs1469038219, COSV67350540; called by muse, mutect2, varscan2
- OR5K4 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100721388, COSV61583414; called by muse, mutect2
- OR5T3 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV100282764, COSV57379949; called by muse, mutect2, varscan2
- OR7D4 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100432679, COSV58072508; called by muse, mutect2, varscan2
- OR8S1 | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV59599512; called by muse, mutect2, varscan2
- OR8U1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56418541; called by muse, mutect2, varscan2
- PARP8 | c.2219C>T p.S740L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV55859278; called by muse, mutect2, varscan2
- PC | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV58922864; called by muse, mutect2, varscan2
- PCARE | c.2573C>T p.S858F | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV59057919; called by muse, mutect2, varscan2
- PCDH8 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV58815034; called by muse, mutect2, varscan2
- PCDHAC1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); catalogued as rs781792274, COSV53845759; called by muse, mutect2, varscan2
- PCDHB12 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV53396899, COSV53397773; called by muse, mutect2, varscan2
- PCLO | c.13621G>A p.G4541R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61626851; called by muse, mutect2, varscan2
- PDZD2 | c.3107G>A p.G1036D | Missense Mutation (SNP) | VAF 83/157 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56872123; called by muse, mutect2, varscan2
- PEAR1 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52773209; called by muse, mutect2, varscan2
- PHEX | c.1646-1G>A p.X549_splice | Splice Site (SNP) | VAF 31/190 reads (16%) | catalogued as COSV65077466, COSV65078745; called by muse, mutect2, varscan2
- PIM1 | c.431C>G p.A144G | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV100998751; called by muse, mutect2, varscan2
- PJVK | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100910538; called by muse, mutect2, varscan2
- PKP2 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs267603443, COSV50731465, COSV99297728; called by muse, mutect2, varscan2
- PKP3 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.157); catalogued as rs1325110281, COSV58989952; called by muse, mutect2, varscan2
- PLCB3 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs929120823, COSV54191608; called by muse, mutect2, varscan2
- PLCB4 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs267606065, COSV53817173; called by muse, mutect2, varscan2
- PLCZ1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56853408; called by muse, mutect2, varscan2
- PLPP3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64840239; called by muse, mutect2, varscan2
- POGLUT2 | c.1414C>G p.Q472E | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0.052); catalogued as COSV65683579; called by muse, mutect2, varscan2
- POM121L12 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV101374883; called by muse, mutect2
- POU4F1 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65885061; called by muse, mutect2, varscan2
- PPP1R3A | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52892677; called by muse, mutect2, varscan2
- PREX2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV55756774, COSV55797706; called by muse, mutect2, varscan2
- PRICKLE2 | c.1088C>T p.S363L (on ENST00000295902; = p.S307L on NM_198859.4) | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55771484; called by muse, mutect2, varscan2
- PTH1R | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV57317732; called by muse, mutect2, varscan2
- PTPRT | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV62017788; called by muse, mutect2, varscan2
- RABEP1 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52588275; called by muse, mutect2, varscan2
- RAD9A | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57237389; called by muse, mutect2, varscan2
- RBM47 | c.802C>A p.Q268K | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as COSV55940247, COSV55943066; called by muse, mutect2
- RGS7 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58542358; called by muse, mutect2, varscan2
- RGS9 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99287887; called by muse, mutect2, varscan2
- RGS9 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99287889; called by muse, mutect2, varscan2
- RHOXF1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV54295722; called by muse, mutect2, varscan2
- RNF123 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59692321; called by muse, mutect2, varscan2
- ROBO4 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs754700384, COSV100127793; called by muse, mutect2, varscan2
- RP1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV55111269; called by muse, mutect2, varscan2
- RP1 | c.1382A>T p.K461I | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55126095; called by muse, mutect2, varscan2
- RP1L1 | c.4192G>A p.G1398R | Missense Mutation (SNP) | VAF 176/654 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV66759993; called by muse, mutect2, varscan2
- RPTN | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 114/558 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs866577758, COSV60166417; called by muse, mutect2, varscan2
- RTEL1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); catalogued as rs868294176, COSV100542742; called by muse, mutect2, varscan2
- RTN3 | c.2206C>T p.L736F (on ENST00000377819 / NM_001265589.2; = p.L717F on NM_201428.3) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs574449790, COSV58029434; called by muse, mutect2, varscan2
- RXFP2 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV53640853; called by muse, mutect2, varscan2
- SAA2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV56778055; called by muse, mutect2, varscan2
- SAMD3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV63719591; called by muse, mutect2, varscan2
- SARDH | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as COSV53835733; called by muse, mutect2
- SCN10A | c.3715G>A p.E1239K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101479289, COSV71860462; called by muse, mutect2, varscan2
- SCN10A | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1294999278, COSV71861574; called by muse, mutect2, varscan2
- SCN5A | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV61121356; called by muse, mutect2, varscan2
- SCN5A | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV61140148; called by muse, mutect2, varscan2
- SCUBE1 | c.1597A>T p.K533* | Nonsense Mutation (SNP) | VAF 20/212 reads (9%) | catalogued as COSV62616135; called by muse, mutect2, varscan2
- SDC1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.723); catalogued as COSV54338805; called by muse, mutect2, varscan2
- SDK2 | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1222334523, COSV66195660; called by muse, mutect2
- SEMA3F | c.1815C>T p.A605= | Splice Region (SNP) | VAF 22/82 reads (27%) | catalogued as rs781505281, COSV50035773; called by muse, mutect2, varscan2
- SEPTIN10 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61781993; called by muse, mutect2, varscan2
- SERAC1 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs377093909; called by muse, mutect2, varscan2
- SERPINB11 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.23); catalogued as COSV66957029, COSV66957793; called by muse, mutect2, varscan2
- SERTAD4 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV65400203; called by muse, mutect2, varscan2
- SETD5 | c.3557G>A p.R1186Q | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1479414341, COSV56717186; called by muse, mutect2, varscan2
- SF3B1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 80/261 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1047501781, COSV59226878; called by muse, mutect2, varscan2
- SH3RF1 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV52925146; called by muse, mutect2, varscan2
- SHH | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV51920263; called by muse, mutect2, varscan2
- SIMC1 | c.107G>A p.R36K (on ENST00000443967 / NM_001308196.1; = p.R55K on NM_001308195.2) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57906702; called by muse, mutect2, varscan2
- SLC16A2 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52088705; called by muse, mutect2, varscan2
- SLC18A3 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV60332621; called by muse, mutect2, varscan2
- SLC26A9 | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 73/393 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV61605346; called by muse, mutect2, varscan2
- SLC30A8 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV69976020; called by muse, mutect2, varscan2
- SLC35F4 | c.693C>T p.F231= (on ENST00000339762 / NM_001352015.2; = p.F195= on NM_001206920.1 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 15/48 reads (31%) | catalogued as COSV60263414; called by muse, mutect2, varscan2
- SLC38A1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV67064889; called by muse, mutect2, varscan2
- SLC45A4 | c.2333C>T p.S778L (on ENST00000517878 / NM_001286646.2; = p.R725C on NM_001080431.2) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.144); catalogued as rs151336979; called by muse, mutect2, varscan2
- SLC9A7 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1160191320, COSV60378558; called by muse, mutect2, varscan2
- SMARCAL1 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV61920334; called by muse, mutect2, varscan2
- SNTG2 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1248389475, COSV57967880; called by muse, mutect2, varscan2
- SOX6 | c.1811A>C p.E604A (on ENST00000528429 / NM_001145819.2; = p.E577A on NM_017508.3) | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV57057679; called by muse, mutect2, varscan2
- SPATA17 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946419972, COSV65121692; called by muse, mutect2, varscan2
- SPEN | c.8608G>A p.G2870S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV65367333; called by muse, mutect2, varscan2
- SPICE1 | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55624770; called by muse, mutect2, varscan2
- SPTA1 | c.5621G>A p.R1874Q | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs201233455, COSV63749381; called by muse, mutect2, varscan2
- SPTA1 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63752900, COSV63755020; called by muse, mutect2, varscan2
- SPTBN5 | c.6010C>T p.Q2004* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs760555874, COSV58027801; called by muse, mutect2, varscan2
- SRCAP | c.8642C>T p.P2881L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs377394919; called by muse, mutect2, varscan2
- STAMBPL1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.994); catalogued as rs1257765689, COSV64223069; called by muse, mutect2, varscan2
- STK16 | c.314C>G p.T105R | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50282650, COSV99850467; called by muse, mutect2, varscan2
- STRN | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55751981; called by muse, mutect2, varscan2
- SYCP2 | c.140T>C p.F47S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV62772392; called by muse, mutect2, varscan2
- SYT2 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV66143164; called by muse, mutect2, varscan2
- TACR3 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100510828; called by muse, mutect2, varscan2
- TAF1L | c.3053C>T p.S1018F | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54268786; called by mutect2, varscan2
- TAF1L | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs780833986, COSV54268796; called by muse, mutect2, varscan2
- TBC1D8B | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs769746560, COSV52176794; called by muse, mutect2, varscan2
- TBX19 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.051); catalogued as COSV63197699; called by muse, mutect2
- TCF20 | c.5371C>T p.R1791C | Missense Mutation (SNP) | VAF 49/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1429923286, COSV59495764; called by muse, mutect2, varscan2
- TECTA | c.4896T>A p.D1632E | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50801009; called by muse, varscan2
- TENM3 | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69318726; called by muse, mutect2, varscan2
- TERF2IP | c.824T>A p.I275K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV55614234; called by muse, mutect2, varscan2
- THRB | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs756399184, COSV62841821; called by muse, mutect2, varscan2
- THSD7B | c.3340G>A p.E1114K (on ENST00000272643; = p.E1112K on NM_001316349.2) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV55652012; called by muse, mutect2, varscan2
- TKTL2 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54921180; called by muse, mutect2, varscan2
- TLE1 | c.493C>T p.L165F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs201385680, COSV64686546; called by muse, mutect2
- TLL1 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | catalogued as COSV99288686; called by muse, mutect2, varscan2
- TLR3 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV57170363; called by muse, mutect2, varscan2
- TLR4 | c.2150C>T p.A717V (on ENST00000355622 / NM_138554.5; = p.A677V on NM_003266.4) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1421321541, COSV100842714, COSV62924197; called by muse, mutect2, varscan2
- TLR8 | c.692A>G p.N231S (on ENST00000218032 / NM_138636.5; = p.N249S on NM_016610.4) | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); catalogued as COSV54320496; called by muse, mutect2
- TMC5 | c.797G>A p.S266N | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV66868610; called by muse, mutect2, varscan2
- TMEM132B | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.168); catalogued as COSV100170631, COSV100171412; called by muse, mutect2, varscan2
- TMEM163 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV56112493; called by muse, mutect2, varscan2
- TMEM178A | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs1354485573, COSV56141960; called by muse, mutect2, varscan2
- TNIP2 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs553726958, COSV59570156; called by muse, mutect2, varscan2
- TNMD | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV65977325, COSV65977777; called by muse, mutect2, varscan2
- TNR | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV54912336; called by muse, mutect2, varscan2
- TNXB | c.12125G>A p.G4042E (on ENST00000647633; = p.G3795E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV64474883; called by muse, mutect2, varscan2
- TPO | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.027); catalogued as rs145974595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAFD1 | c.48-2A>T p.X16_splice | Splice Site (SNP) | VAF 21/79 reads (27%) | catalogued as COSV57506431; called by muse, mutect2, varscan2
- TRAV12-1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs775700428; called by muse, mutect2, varscan2
- TRDMT1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 29/123 reads (24%) | catalogued as COSV58320861; called by muse, mutect2, varscan2
- TRIM25 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV100380922, COSV57545823; called by muse, mutect2, varscan2
- TRMT9B | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV101501646; called by muse, mutect2
- TRPC7 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs867678481, COSV61463426; called by muse, mutect2
- TSHZ1 | c.2363C>T p.P788L (on ENST00000580243 / NM_001308210.2; = p.P743L on NM_005786.6) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV59016604; called by muse, mutect2, varscan2
- TSKS | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55876159; called by muse, mutect2, varscan2
- TTLL8 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as rs766780524, COSV99838553, COSV99838700; called by muse, mutect2, varscan2
- TTN | c.83878G>A p.G27960R (on ENST00000591111; = p.G20536R on NM_003319.4) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | PolyPhen probably damaging (0.964); catalogued as COSV59934099; called by muse, mutect2, varscan2
- TTN | c.6230C>T p.A2077V (on ENST00000591111; = p.A2031V on NM_003319.4) | Missense Mutation (SNP) | VAF 34/94 reads (36%) | PolyPhen probably damaging (0.997); catalogued as rs1302072310, COSV60333310; called by muse, mutect2, varscan2
- TXNL4B | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as rs773021440, COSV51703493; called by mutect2, varscan2
- UGT2B17 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV58502592; called by muse, varscan2
- UMODL1 | c.152T>C p.V51A | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV68577825; called by muse, mutect2, varscan2
- UNC13C | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV52871167, COSV99512840; called by muse, mutect2, varscan2
- UNC79 | c.4199A>G p.K1400R (on ENST00000393151 / NM_001346218.2; = p.K1223R on NM_020818.5) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.91); catalogued as COSV56409267; called by muse, mutect2, varscan2
- USH2A | c.10613G>A p.R3538Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs774844491, COSV56328634; ClinVar: uncertain significance; called by mutect2, varscan2
- USP26 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV63708364, COSV63709713; called by muse, mutect2, varscan2
- UTP25 | c.1808T>C p.L603S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71966178; called by muse, mutect2, varscan2
- VCAM1 | c.1280T>C p.V427A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV54117908; called by muse, mutect2, varscan2
- VGLL3 | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV68209934; called by muse, mutect2
- VRK1 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1261685595, COSV53711454; called by muse, mutect2
- VWA3B | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV68246565; called by muse, mutect2, varscan2
- VWA8 | c.1835T>G p.V612G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV55705159; called by muse, mutect2, varscan2
- WDR20 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV54475036; called by muse, mutect2, varscan2
- WEE2 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV66880058; called by muse, mutect2, varscan2
- WNT2B | c.1144C>T p.P382S (on ENST00000369684 / NM_024494.3; = p.P363S on NM_004185.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV99861912; called by muse, mutect2, varscan2
- WSCD1 | c.1012A>T p.T338S | Missense Mutation (SNP) | VAF 101/381 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.038); catalogued as COSV58498215; called by muse, mutect2, varscan2
- WWC1 | c.2792C>T p.S931F | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54658302; called by muse, mutect2, varscan2
- XIRP2 | c.1966G>A p.E656K (on ENST00000628543; = p.E831K on NM_152381.6) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54679776, COSV99748346; called by muse, mutect2, varscan2
- XKR9 | c.730A>T p.I244L | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV68773502; called by muse, mutect2, varscan2
- YTHDC1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV60012014; called by muse, mutect2, varscan2
- ZBED9 | c.2914G>T p.G972C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71729533; called by muse, mutect2
- ZBED9 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.068); catalogued as COSV71729373; called by muse, mutect2, varscan2
- ZBTB44 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs1346205081, COSV63538463; called by muse, mutect2
- ZBTB44 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.358); catalogued as COSV63538469; called by muse, mutect2
- ZBTB7C | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs758871407, COSV100134566; called by muse, varscan2
- ZFPM2 | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV65875773; called by muse, mutect2, varscan2
- ZNF229 | c.1328G>A p.C443Y | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV52164805, COSV99350559; called by muse, mutect2, varscan2
- ZNF35 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV56077440; called by muse, mutect2, varscan2
- ZNF354A | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs758506196, COSV59984900; called by muse, mutect2, varscan2
- ZNF367 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64547729; called by muse, mutect2, varscan2
- ZNF493 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62749149; called by muse, varscan2
- ZNF521 | c.3874C>T p.P1292S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV64131718; called by muse, mutect2, varscan2
- ZNF548 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs773379443, COSV60241926; called by muse, mutect2, varscan2
- ZNF554 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1247344866, COSV57886986; called by muse, mutect2, varscan2
- ZNF626 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV74128857; called by muse, mutect2, varscan2
- ZNF638 | c.3463A>C p.T1155P | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52496608; called by muse, mutect2, varscan2
- ZNF695 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV60586182, COSV60587474; called by muse, mutect2, varscan2
- ZNF804A | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1465760741, COSV56470507; called by muse, mutect2, varscan2
- ZNF808 | c.2332C>T p.L778F | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1176937259, COSV63121640; called by muse, mutect2
- ZNRF4 | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV55776220; called by muse, mutect2, varscan2
- ZNRF4 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV55776228; called by muse, mutect2, varscan2
- ZSCAN20 | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1416595464, COSV63684518; called by muse, mutect2, varscan2
- ZWINT | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV59186117, COSV59186318; called by muse, mutect2, varscan2
- ZXDA | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as rs923124772, COSV62388846; called by muse, mutect2
- EPS15 | c.2052+2T>C p.X684_splice | Splice Site (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- FAM9C | c.176_182+17del p.X59_splice | Splice Site (DEL) | VAF 40/235 reads (17%) | called by mutect2, pindel
- FRG2C | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.115); called by muse, mutect2
- HUWE1 | c.9912_9915dup p.S3306Afs*6 | Frame Shift Ins (INS) | VAF 19/81 reads (23%) | called by mutect2, pindel, varscan2
- IGKV1D-13 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by mutect2, varscan2
- MRC1 | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- NBPF15 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 354/678 reads (52%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAMEF20 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 107/305 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PRAMEF20 | c.1322T>A p.V441E | Missense Mutation (SNP) | VAF 111/308 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- STPG1 | c.350_352delinsTA p.P117Lfs*24 (on ENST00000337248 / NM_001199013.2; = p.P70Lfs*24 on NM_178122.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | called by pindel, varscan2*
- STRN | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.045); called by muse, mutect2
- TRAV8-4 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ABCC3 | c.1308G>A p.Q436= | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as COSV53328619; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1152C>T p.F384= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV56473968; called by muse, mutect2
- ADAMTS18 | c.2640C>T p.I880= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs148705153, COSV51422871; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2085C>T p.S695= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1040323881; called by muse, mutect2, varscan2
- ADGRG4 | c.7806G>A p.G2602= | Silent (SNP) | VAF 83/223 reads (37%) | catalogued as COSV54963978, COSV54964299; called by muse, mutect2, varscan2
- ADGRV1 | c.14880C>T p.F4960= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs1188529416, COSV67982526, COSV67984262; called by muse, mutect2, varscan2
- ADNP2 | c.3186C>T p.F1062= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV51542259; called by muse, mutect2, varscan2
- AKAP14 | c.558C>T p.F186= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV57631310; called by muse, mutect2, varscan2
- AKAP6 | c.6189C>T p.I2063= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV55232489; called by muse, mutect2, varscan2
- ALB | c.429G>A p.E143= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs1252348883, COSV55742364; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2970G>A p.Q990= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV51857812; called by muse, mutect2, varscan2
- APOB | c.12492C>T p.F4164= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as COSV51951404; called by muse, mutect2, varscan2
- AQP8 | c.150C>T p.F50= | Silent (SNP) | VAF 65/275 reads (24%) | catalogued as COSV54847089; called by muse, mutect2, varscan2
- ARHGAP25 | c.1332C>T p.L444= (on ENST00000409202 / NM_001007231.3; = p.L436= on NM_014882.3) | Silent (SNP) | VAF 52/169 reads (31%) | catalogued as COSV54908834; called by muse, mutect2, varscan2
- ARHGAP39 | c.738C>T p.S246= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as rs370518375; called by muse, mutect2, varscan2
- ASIC3 | c.942G>A p.G314= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV52525718; called by muse, mutect2, varscan2
- ASTN1 | c.3045C>A p.L1015= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV62505919; called by muse, mutect2
- BCAR1 | c.249C>T p.A83= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV50802880; called by muse, mutect2, varscan2
- BPIFB3 | c.81G>A p.T27= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as rs149497264; called by muse, mutect2, varscan2
- BTNL3 | c.1281C>T p.S427= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV61565843; called by muse, mutect2, varscan2
- C16orf89 | c.225C>T p.V75= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV60126494; called by muse, mutect2, varscan2
- CACNA1C | c.813C>T p.I271= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs747169285, COSV59709894, COSV59760797; called by muse, mutect2, varscan2
- CACNA1G | c.3777C>T p.F1259= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV61738750; called by muse, mutect2, varscan2
- CADM2 | c.855C>T p.F285= (on ENST00000407528 / NM_001167674.2; = p.F287= on NM_153184.4) | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV67376010; called by muse, mutect2, varscan2
- CAPRIN1 | c.2025G>A p.K675= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as COSV58222314; called by muse, mutect2, varscan2
- CAPZA3 | c.453G>A p.L151= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV56858471; called by muse, mutect2, varscan2
- CARMIL2 | c.208C>T p.L70= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV58031700; called by muse, mutect2, varscan2
- CASR | c.960C>T p.F320= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs753011255, COSV56133741; ClinVar: likely benign; called by muse, mutect2, varscan2
- CASR | c.1644C>T p.F548= (on ENST00000490131; = p.F625= on NM_000388.4) | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs761716567, COSV56135487; called by muse, mutect2, varscan2
- CCR8 | c.861C>T p.I287= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV58336921; called by muse, mutect2, varscan2
- CD28 | c.417C>T p.H139= | Silent (SNP) | VAF 54/159 reads (34%) | catalogued as COSV60731207; called by muse, mutect2, varscan2
- CD68 | c.465G>A p.E155= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV51512263; called by muse, mutect2, varscan2
- CFAP77 | c.870G>A p.T290= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs757308234, COSV58016790; called by muse, mutect2, varscan2
- CFTR | c.3045C>T p.I1015= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV50096089; called by muse, mutect2, varscan2
- CHD8 | c.870C>T p.V290= (on ENST00000646647 / NM_001170629.2; = p.V11= on NM_020920.4) | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs1429133890, COSV67872608; called by muse, mutect2, varscan2
- CHRM3 | c.918G>A p.R306= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs545390756, COSV55103518; called by muse, mutect2, varscan2
- CHST8 | c.1251C>T p.S417= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99381513; called by muse, mutect2, varscan2
- CLEC3A | c.318C>T p.S106= (on ENST00000651443; = p.S97= on NM_005752.6) | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1381741267, COSV100222339; called by muse, mutect2, varscan2
- CLSTN1 | c.1422G>A p.V474= (on ENST00000377298 / NM_001009566.3; = p.V464= on NM_014944.4) | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs1364702142, COSV63650917; called by muse, mutect2, varscan2
- CLSTN2 | c.1575C>T p.R525= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV71724911; called by muse, mutect2, varscan2
- COG8 | c.573C>T p.I191= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV54743524; called by muse, mutect2, varscan2
- COL14A1 | c.489C>T p.V163= | Silent (SNP) | VAF 104/204 reads (51%) | catalogued as rs149492812; called by muse, mutect2, varscan2
- COL4A4 | c.4116G>A p.V1372= | Silent (SNP) | VAF 54/332 reads (16%) | catalogued as rs1210526365, COSV61636392; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL4A4 | c.1122C>T p.F374= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV61631053; called by muse, mutect2, varscan2
- CPE | c.834C>T p.F278= | Silent (SNP) | VAF 86/374 reads (23%) | catalogued as COSV68579471; called by muse, mutect2, varscan2
- CPED1 | c.2862C>T p.F954= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as rs1418776754, COSV60012779; called by muse, mutect2
- CPN2 | c.1431C>T p.A477= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV60471857; called by muse, mutect2, varscan2
- CRAT | c.1698C>T p.F566= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs759235861, COSV58877141; called by muse, mutect2, varscan2
- CYLC1 | c.531C>T p.S177= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs899619640, COSV61415717; called by muse, mutect2, varscan2
- CYP2C19 | c.1140C>T p.L380= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs868401281, COSV64909336; called by muse, mutect2, varscan2
- CYP4F11 | c.1281C>T p.I427= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as rs891456333, COSV56129387; called by muse, mutect2, varscan2
- CYP4F11 | c.858C>T p.F286= | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as COSV56126107; called by muse, mutect2, varscan2
- CYRIA | c.765G>A p.V255= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV62867132; called by muse, mutect2, varscan2
- DCLK2 | c.723C>T p.V241= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs774083374, COSV56211846, COSV99651641; called by muse, mutect2, varscan2
- DDX18 | c.1578C>T p.A526= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV54309107; called by muse, mutect2, varscan2
- DENND2C | c.405G>A p.E135= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV67923979; called by muse, mutect2, varscan2
- DENND3 | c.738C>T p.F246= | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as rs531198735, COSV52801888; called by muse, mutect2, varscan2
- DIP2B | c.4620G>A p.V1540= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs781370617, COSV99999163; called by muse, mutect2, varscan2
- DNAH2 | c.6246C>T p.I2082= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs1182834915, COSV66717149; called by muse, mutect2, varscan2
- DNAH5 | c.7344G>A p.E2448= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as rs766413623, COSV54250531; called by muse, mutect2, varscan2
- DNAI2 | c.1647G>A p.E549= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV56762365; called by muse, mutect2, varscan2
- DNAJC16 | c.1038G>A p.K346= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as COSV65449449; called by muse, mutect2, varscan2
- DOP1B | c.1773C>T p.I591= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as rs141312847; called by muse, mutect2, varscan2
- EGF | c.531G>A p.E177= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV54484434; called by muse, mutect2, varscan2
- ENPEP | c.684G>A p.R228= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV54451248; called by muse, mutect2, varscan2
- EPHA1 | c.303C>T p.F101= | Silent (SNP) | VAF 85/278 reads (31%) | catalogued as COSV51976195; called by muse, mutect2, varscan2
- ERG | c.1215C>T p.A405= (on ENST00000398919 / NM_001243428.1; = p.A381= on NM_004449.4) | Silent (SNP) | VAF 46/177 reads (26%) | catalogued as COSV55739157; called by muse, mutect2, varscan2
- ERICH6 | c.924C>T p.I308= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV55802116; called by muse, mutect2, varscan2
- ERN1 | c.2841C>T p.A947= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV70504651; called by muse, mutect2, varscan2
- FAM111A | c.1536C>T p.V512= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as rs201314346, COSV64655862; called by muse, mutect2, varscan2
- FAM47C | c.450G>A p.L150= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs1171930673, COSV63730242; called by muse, mutect2, varscan2
- FANCB | c.2139C>T p.F713= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as rs1312005700, COSV60759454; called by muse, mutect2, varscan2
- FANCF | c.402C>T p.A134= | Silent (SNP) | VAF 100/295 reads (34%) | catalogued as rs774333200, COSV59417129; called by muse, mutect2, varscan2
- FGD1 | c.1053G>A p.K351= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV64309624; called by muse, mutect2, varscan2
- FKBP15 | c.2691C>T p.S897= | Silent (SNP) | VAF 34/142 reads (24%) | catalogued as COSV53033676; called by muse, mutect2, varscan2
- FLVCR1 | c.372G>A p.Q124= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs1251461956, COSV63134480; called by muse, mutect2, varscan2
- FZD4 | c.342T>C p.I114= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as COSV72294708; called by muse, mutect2, varscan2
- GAS7 | c.786C>T p.S262= (on ENST00000432992 / NM_201433.2; = p.S122= on NM_003644.3) | Silent (SNP) | VAF 71/229 reads (31%) | catalogued as COSV100096676; called by muse, mutect2, varscan2
- GHDC | c.1065C>T p.D355= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100054895; called by muse, varscan2
- GHDC | c.1014C>T p.L338= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as COSV100054753; called by muse, varscan2
- GLRA3 | c.1089G>A p.L363= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV56869789, COSV99927388; called by muse, mutect2, varscan2
- GPR75 | c.564C>T p.L188= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV61832187; called by muse, mutect2, varscan2
- GPR89A | c.306C>T p.I102= | Silent (SNP) | VAF 47/331 reads (14%) | catalogued as rs782567174, COSV58260525; called by muse, mutect2, varscan2
- GRIN2A | c.2550G>A p.T850= | Silent (SNP) | VAF 50/141 reads (35%) | catalogued as rs750224605, COSV58020783; called by muse, mutect2, varscan2
- GRM3 | c.2478C>T p.I826= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs999736107, COSV64471907; called by muse, mutect2, varscan2
- HECTD4 | c.7896C>T p.V2632= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs1566072861, COSV66399608; called by muse, mutect2, varscan2
- HIC2 | c.1788C>T p.G596= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as COSV68042851; called by muse, mutect2
- HMCN2 | c.2331C>T p.I777= | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- HMGCS2 | c.306C>T p.I102= | Silent (SNP) | VAF 67/173 reads (39%) | catalogued as COSV65568260; called by muse, mutect2, varscan2
- HNRNPH1 | c.1005C>T p.F335= | Silent (SNP) | VAF 83/184 reads (45%) | catalogued as rs757132093, COSV61485915; called by muse, mutect2, varscan2
- HP | c.483G>A p.R161= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV63326419; called by muse, mutect2, varscan2
- HTR2C | c.1035C>T p.L345= | Silent (SNP) | VAF 89/233 reads (38%) | catalogued as COSV52221737; called by muse, mutect2, varscan2
- IKZF3 | c.207G>A p.E69= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs1164607712, COSV53106903; called by muse, mutect2, varscan2
- IQCB1 | c.1452C>T p.A484= | Silent (SNP) | VAF 19/169 reads (11%) | catalogued as COSV100182070; called by muse, mutect2
- ITGA7 | c.1275C>T p.F425= (on ENST00000555728; = p.F381= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs774888135, COSV57696209, COSV57703438; called by muse, mutect2, varscan2
- JAKMIP3 | c.1146C>A p.P382= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV53829036; called by muse, mutect2, varscan2
- KAT2B | c.1026C>T p.I342= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs759038296, COSV55434344; called by muse, mutect2
- KCNN2 | c.573G>A p.R191= (on ENST00000264773; = p.R403= on NM_021614.4) | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV99300514; called by muse, mutect2, varscan2
- KDF1 | c.411C>T p.S137= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1224661330, COSV57672131; called by muse, mutect2, varscan2
- KIAA0100 | c.4177C>T p.L1393= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV101197383; called by muse, mutect2, varscan2
- KIAA0100 | c.4176C>T p.H1392= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV101197384; called by muse, mutect2, varscan2
- KIAA0753 | c.2655C>T p.G885= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV63818913; called by muse, mutect2, varscan2
- KIAA1210 | c.3165C>T p.S1055= | Silent (SNP) | VAF 36/217 reads (17%) | catalogued as rs1196560643, COSV68180053; called by muse, mutect2, varscan2
- KITLG | c.174C>T p.V58= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV57203931; called by muse, mutect2, varscan2
- LGR5 | c.2052C>T p.I684= | Silent (SNP) | VAF 47/243 reads (19%) | catalogued as rs375514954, COSV57008733; called by muse, mutect2, varscan2
- LLCFC1 | c.321G>A p.Q107= (on ENST00000458732; = p.Q76= on NM_178829.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as COSV62337723; called by muse, mutect2, varscan2
- LMNA | c.312G>A p.L104= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV61544030; called by muse, mutect2, varscan2
- LRRC37A2 | c.3981C>G p.V1327= | Silent (SNP) | VAF 88/543 reads (16%) | catalogued as COSV60236735; called by muse, mutect2, varscan2
- MAGEB16 | c.126C>T p.S42= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV67874544; called by muse, mutect2, varscan2
- MAGEC1 | c.2430C>T p.L810= | Silent (SNP) | VAF 125/465 reads (27%) | catalogued as COSV53580949; called by muse, mutect2, varscan2
- MAP1A | c.5574C>T p.S1858= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV55811166; called by muse, mutect2, varscan2
- MAPT | c.921C>T p.S307= (on ENST00000262410 / NM_001377265.1; = p.S232= on NM_016835.4) | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV52247297; called by muse, mutect2, varscan2
- MATN4 | c.615C>T p.F205= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as rs967616997, COSV59215674; called by muse, mutect2, varscan2
- MB21D2 | c.801C>T p.V267= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV66665917; called by muse, mutect2, varscan2
- MBOAT1 | c.1350C>T p.I450= | Silent (SNP) | VAF 11/149 reads (7%) | catalogued as COSV61127771; called by muse, mutect2
- MPRIP | c.588C>T p.V196= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1339092210, COSV59054266; called by muse, mutect2, varscan2
- MUC16 | c.18099C>T p.S6033= | Silent (SNP) | VAF 42/169 reads (25%) | catalogued as COSV67470613, COSV67491892; called by muse, mutect2, varscan2
- MUC2 | c.1968G>A p.K656= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- MYBL2 | c.1288C>T p.L430= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV53833557; called by muse, mutect2, varscan2
- MYL2 | c.63C>T p.F21= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs779983470, COSV57406937; ClinVar: likely benign; called by muse, mutect2
- MYO18B | c.5785C>T p.L1929= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV59147913; called by muse, mutect2, varscan2
- MYO5B | c.3186G>A p.E1062= | Silent (SNP) | VAF 29/69 reads (42%) | catalogued as rs1294929377, COSV99546057; called by muse, mutect2, varscan2
- MYO5B | c.2241C>T p.F747= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV53216175; called by muse, mutect2, varscan2
- MYO9B | c.6306C>T p.R2102= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV55728802; called by muse, mutect2, varscan2
- NALCN | c.5115C>T p.P1705= | Silent (SNP) | VAF 32/173 reads (18%) | catalogued as rs893899221, COSV51964071; called by muse, mutect2, varscan2
- NCKAP5 | c.1635C>T p.P545= | Silent (SNP) | VAF 48/158 reads (30%) | catalogued as COSV58452305; called by muse, mutect2, varscan2
- NEK2 | c.219G>A p.R73= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV65357301; called by muse, mutect2, varscan2
- NEO1 | c.2679C>T p.V893= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV99982624; called by muse, mutect2, varscan2
- NLRP1 | c.2019C>T p.F673= | Silent (SNP) | VAF 42/194 reads (22%) | catalogued as COSV52568266; called by muse, mutect2, varscan2
- NRDE2 | c.3303C>T p.S1101= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV62962262; called by muse, mutect2, varscan2
- NTSR1 | c.1167G>A p.R389= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as rs1314464680, COSV65139304; called by muse, mutect2, varscan2
- NUDCD3 | c.483C>T p.V161= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV62651793; called by muse, mutect2, varscan2
- OPRL1 | c.468C>T p.I156= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as COSV61092391; called by muse, mutect2, varscan2
- OR10R2 | c.654G>A p.V218= | Silent (SNP) | VAF 65/300 reads (22%) | catalogued as COSV63768811, COSV63768829; called by muse, mutect2, varscan2
- OR13G1 | c.852G>A p.P284= | Silent (SNP) | VAF 28/193 reads (15%) | catalogued as rs762243934, COSV62943598, COSV62943875, COSV62944685; called by muse, mutect2, varscan2
- OR2M2 | c.117C>T p.F39= | Silent (SNP) | VAF 261/672 reads (39%) | catalogued as COSV62899376; called by muse, mutect2, varscan2
- OR4E2 | c.348C>T p.I116= | Silent (SNP) | VAF 38/180 reads (21%) | catalogued as rs954148007, COSV57731723; called by muse, varscan2
- OR4K13 | c.591C>T p.L197= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs759397011, COSV59860796; called by muse, mutect2, varscan2
- OR51A4 | c.780C>T p.A260= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs764202521, COSV66750051; called by muse, mutect2
- OR5B21 | c.180C>T p.F60= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV64481650; called by muse, mutect2, varscan2
- OR5R1 | c.480C>T p.T160= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs367575556; called by muse, mutect2
- OR9K2 | c.810G>T p.L270= (on ENST00000305377; = p.L248= on NM_001005243.1) | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV59533401; called by muse, mutect2, varscan2
- P2RY10 | c.816C>A p.T272= | Silent (SNP) | VAF 47/316 reads (15%) | catalogued as COSV50685951; called by muse, mutect2, varscan2
- PACS1 | c.2052C>T p.F684= | Silent (SNP) | VAF 46/173 reads (27%) | catalogued as COSV57699845; called by muse, mutect2, varscan2
- PASK | c.3036C>T p.F1012= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as rs867512588, COSV52148976; called by muse, mutect2, varscan2
- PAX3 | c.942C>T p.P314= | Silent (SNP) | VAF 121/375 reads (32%) | catalogued as COSV60592398; called by muse, mutect2, varscan2
- PCDH18 | c.1068C>T p.I356= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs757688312, COSV61271965; called by muse, mutect2, varscan2
- PCDHA7 | c.1272G>A p.V424= | Silent (SNP) | VAF 81/199 reads (41%) | catalogued as rs1554135164, COSV65347364; called by muse, mutect2, varscan2
- PCDHB11 | c.1152C>A p.S384= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV61311647, COSV61313196; called by muse, mutect2, varscan2
- PCDHGA2 | c.1722C>T p.G574= | Silent (SNP) | VAF 39/300 reads (13%) | catalogued as COSV53912616; called by muse, mutect2, varscan2
- PIK3CB | c.1524C>T p.F508= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs61755418; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIM1 | c.432C>T p.A144= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as COSV100998753; called by muse, mutect2, varscan2
- PJVK | c.603C>T p.F201= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as rs762131024, COSV64307003; called by muse, mutect2, varscan2
- PLA2G4A | c.481A>C p.R161= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV66556814; called by muse, mutect2, varscan2
- PLXNB1 | c.3816C>T p.V1272= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs748948370, COSV56494021; called by muse, mutect2, varscan2
- PLXNB3 | c.2283C>T p.L761= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV62801978; called by muse, mutect2, varscan2
- PLXNB3 | c.2883C>T p.F961= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs376016498, COSV62799050; called by muse, mutect2, varscan2
- POMT2 | c.1089C>T p.P363= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs540688610, COSV55073882; called by muse, mutect2, varscan2
- PPFIA4 | c.2157C>T p.S719= (on ENST00000447715; = p.S720= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV55321444; called by muse, mutect2, varscan2
- PPP2R1A | c.1335C>T p.S445= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as rs1298281898, COSV59048327; called by muse, mutect2, varscan2
- PRAG1 | c.3240C>T p.P1080= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as COSV58166650; called by muse, mutect2, varscan2
- PRDM2 | c.2388C>T p.S796= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV52455236; called by muse, mutect2, varscan2
- PRR14L | c.6081C>T p.T2027= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV57887910; called by muse, mutect2, varscan2
- PRSS22 | c.459C>T p.F153= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV50723940; called by muse, mutect2, varscan2
- PRSS54 | c.1158C>T p.F386= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV54687784; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1644G>A p.A548= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs765822767, COSV54763675; called by muse, mutect2, varscan2
- RAB40AL | c.777C>T p.I259= | Silent (SNP) | VAF 47/171 reads (27%) | catalogued as COSV54434532; called by muse, mutect2, varscan2
- RBM38 | c.579C>T p.A193= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs572196610, COSV61135229; called by muse, mutect2, varscan2
- RGS6 | c.15C>T p.S5= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs774370078, COSV59598292; called by muse, mutect2, varscan2
- RHOH | c.384C>T p.A128= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV67806793; called by muse, mutect2, varscan2
- ROBO4 | c.936C>T p.G312= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100127794; called by muse, mutect2, varscan2
- RPRD2 | c.2436C>T p.S812= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV64823226; called by muse, mutect2, varscan2
- RPRD2 | c.3729C>T p.P1243= | Silent (SNP) | VAF 13/240 reads (5%) | catalogued as COSV64823233; called by muse, mutect2
- RSBN1 | c.195G>A p.Q65= | Silent (SNP) | VAF 22/205 reads (11%) | catalogued as COSV54735126; called by muse, mutect2, varscan2
- RSRC1 | c.342C>T p.L114= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV55838561, COSV99907281; called by muse, mutect2
- RTEL1 | c.219C>T p.A73= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs781340943, COSV100542744; ClinVar: likely benign; called by muse, mutect2, varscan2
- RTL1 | c.33G>T p.T11= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV66017465; called by muse, mutect2, varscan2
- RTL9 | c.1416T>G p.T472= | Silent (SNP) | VAF 49/263 reads (19%) | catalogued as COSV71825708; called by muse, mutect2, varscan2
- RYR1 | c.3270G>A p.E1090= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as rs577203385, COSV62110182; called by muse, mutect2, varscan2
- SCN1A | c.2643G>A p.K881= (on ENST00000303395 / NM_001202435.3; = p.K870= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV57681101; called by muse, mutect2, varscan2
- SELP | c.1545C>T p.S515= | Silent (SNP) | VAF 27/195 reads (14%) | catalogued as COSV55258249; called by muse, mutect2, varscan2
- SEMG1 | c.496C>T p.L166= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as rs200995588, COSV54875459; called by muse, mutect2, varscan2
- SERPINB10 | c.507C>T p.L169= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs374016764; called by muse, mutect2, varscan2
- SETDB1 | c.333C>T p.S111= | Silent (SNP) | VAF 67/147 reads (46%) | catalogued as COSV54992074; called by muse, mutect2, varscan2
- SIGLEC7 | c.1143G>A p.K381= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV58317758; called by muse, mutect2, varscan2
- SLC1A5 | c.768C>T p.I256= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV69467040, COSV69467470; called by muse, mutect2, varscan2
- SLC37A3 | c.1041C>T p.G347= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs762510855, COSV58268434; called by muse, mutect2, varscan2
- SLCO2B1 | c.1120C>T p.L374= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV56939329; called by muse, mutect2, varscan2
- SMARCC2 | c.1341C>G p.P447= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV57224712; called by muse, mutect2, varscan2
- SMC4 | c.1998A>C p.A666= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV61007839; called by muse, mutect2, varscan2
- SPTBN4 | c.1647C>T p.D549= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs757860353, COSV58958241; called by muse, mutect2
- ST6GAL2 | c.1314C>T p.F438= | Silent (SNP) | VAF 39/151 reads (26%) | catalogued as COSV62416661; called by muse, mutect2, varscan2
- ST6GAL2 | c.450C>T p.F150= | Silent (SNP) | VAF 93/270 reads (34%) | catalogued as rs1279213386, COSV64525979, COSV64531635; called by muse, mutect2, varscan2
- SYT9 | c.1359C>T p.I453= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs762713738, COSV100608031, COSV59624727; called by muse, mutect2, varscan2
- TACR3 | c.648C>T p.F216= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs1163611224, COSV59206673; called by muse, mutect2, varscan2
- TACR3 | c.498C>T p.I166= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV59208405; called by muse, mutect2, varscan2
- TBC1D10C | c.768C>T p.F256= | Silent (SNP) | VAF 59/254 reads (23%) | catalogued as COSV56705195; called by muse, mutect2, varscan2
- TBX10 | c.861G>A p.R287= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs781730476, COSV56875256; called by muse, mutect2, varscan2
- TC2N | c.1230G>A p.L410= | Silent (SNP) | VAF 83/332 reads (25%) | catalogued as COSV61748171; called by muse, mutect2, varscan2
- TEAD2 | c.1116C>T p.Y372= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV60545242; called by muse, mutect2, varscan2
- TENM3 | c.3522C>T p.A1174= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV69318737; called by muse, mutect2, varscan2
- THBS2 | c.345C>T p.I115= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs267600897, COSV64676991, COSV64681678; called by muse, mutect2, varscan2
- THRB | c.1023G>A p.L341= | Silent (SNP) | VAF 21/208 reads (10%) | catalogued as COSV54980547; called by muse, mutect2, varscan2
- TLL1 | c.2109C>T p.S703= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV99288683; called by muse, mutect2, varscan2
- TMEM132B | c.1161G>A p.G387= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV54773177; called by muse, mutect2, varscan2
- TNFRSF10D | c.816G>A p.E272= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs776361997, COSV57037966; called by muse, mutect2, varscan2
- TNN | c.2290C>T p.L764= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as COSV53435063; called by muse, mutect2, varscan2
- TNS4 | c.1386G>T p.L462= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV54187934; called by muse, mutect2, varscan2
- TRAV10 | c.57G>A p.G19= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- TRBJ2-2 | c.16C>T p.L6= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- TRPC7 | c.678G>A p.A226= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100725417, COSV61463439; called by muse, mutect2, varscan2
- TRPM2 | c.4320C>T p.I1440= | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as rs776018491, COSV55965137; called by muse, mutect2, varscan2
- TSSK2 | c.24G>A p.R8= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as COSV52818785; called by muse, mutect2, varscan2
- TTN | c.12063G>A p.Q4021= (on ENST00000591111; = p.Q3975= on NM_003319.4) | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV100625706; called by muse, mutect2, varscan2
- TTN | c.2940C>T p.D980= (on ENST00000591111; = p.D934= on NM_003319.4) | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as rs201395853, COSV60297478; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBA1 | c.1839C>T p.F613= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV60115395; called by muse, mutect2, varscan2
- UBD | c.456G>A p.K152= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV63544453; called by muse, mutect2, varscan2
- UPF1 | c.2391G>A p.K797= (on ENST00000599848 / NM_001297549.2; = p.K786= on NM_002911.4) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV53201478; called by muse, mutect2, varscan2
- WNT2B | c.1143C>T p.A381= (on ENST00000369684 / NM_024494.3; = p.A362= on NM_004185.4) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs145437043; called by muse, mutect2, varscan2
- WRAP53 | c.861G>A p.P287= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs1399107184, COSV56834836; called by muse, mutect2, varscan2
- XIRP2 | c.8202C>T p.V2734= (on ENST00000628543; = p.V2909= on NM_152381.6) | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV54692421, COSV54732803; called by muse, mutect2, varscan2
- ZBTB26 | c.855G>A p.L285= | Silent (SNP) | VAF 43/177 reads (24%) | catalogued as COSV65403476; called by muse, mutect2, varscan2
- ZBTB32 | c.108G>A p.G36= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs754384073, COSV52892468; called by muse, mutect2, varscan2
- ZNF260 | c.1143C>T p.I381= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV72951292; called by muse, mutect2, varscan2
- ZNF443 | c.441G>A p.G147= | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as COSV56894223; called by muse, mutect2, varscan2
- ZNF560 | c.774C>T p.T258= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV56871521; called by muse, mutect2, varscan2
- ZNF564 | c.351C>T p.S117= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV59434724; called by muse, mutect2, varscan2
- ZNF782 | c.975C>T p.L325= | Silent (SNP) | VAF 45/148 reads (30%) | catalogued as COSV56653055, COSV56654114; called by muse, mutect2, varscan2
- ATP2B2 | c.*226C>T | 3'UTR (SNP) | VAF 25/90 reads (28%) | catalogued as rs1426967358, COSV59496014; called by muse, mutect2, varscan2
- CABYR | c.*17-474C>T | Intron (SNP) | VAF 18/97 reads (19%) | catalogued as COSV59112742; called by muse, mutect2, varscan2
- CHCHD2P9 | n.406G>A | RNA (SNP) | VAF 19/90 reads (21%) | catalogued as rs777240231; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33839C>T | Intron (SNP) | VAF 49/115 reads (43%) | catalogued as COSV100281724; called by muse, mutect2, varscan2
- DCHS2 | n.5276C>T | RNA (SNP) | VAF 34/92 reads (37%) | catalogued as COSV61779203; called by muse, mutect2, varscan2
- DEFB110 | c.*2G>A | 3'UTR (SNP) | VAF 12/46 reads (26%) | catalogued as rs144223291; called by muse, mutect2, varscan2
- DKC1 | c.771+174G>A | Intron (SNP) | VAF 52/151 reads (34%) | catalogued as COSV101059898; called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445492 C>T | 3'Flank (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.275G>A | RNA (SNP) | VAF 34/309 reads (11%) | catalogued as rs765753033; called by muse, mutect2
- KIF1B | c.2115+7075dup | Intron (INS) | VAF 72/222 reads (32%) | called by mutect2, pindel, varscan2
- MARVELD3 | chr16:71640468 G>A | 3'Flank (SNP) | VAF 24/87 reads (28%) | catalogued as COSV51704953; called by muse, mutect2, varscan2
- RPP38 | chr10:15096531 C>T | 5'Flank (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- SLC25A48 | c.679+127C>T | Intron (SNP) | VAF 15/29 reads (52%) | catalogued as COSV50851355; called by muse, mutect2, varscan2
- TMEM99 | n.429C>T | RNA (SNP) | VAF 34/135 reads (25%) | catalogued as COSV56984154; called by muse, mutect2, varscan2
- TTN | c.34265-4550G>A | Intron (SNP) | VAF 28/120 reads (23%) | catalogued as COSV100625705, COSV60032991, COSV60398555; called by muse, mutect2, varscan2
- TTN | c.10360+1222G>A | Intron (SNP) | VAF 57/187 reads (30%) | catalogued as rs1170012025, COSV59866137, COSV59939083; called by muse, mutect2, varscan2
- WDR54 | c.*1G>A | 3'UTR (SNP) | VAF 66/201 reads (33%) | catalogued as COSV99269874; called by muse, mutect2, varscan2
- XIRP2 | c.*1458C>A | 3'UTR (SNP) | VAF 33/100 reads (33%) | catalogued as COSV99746384; called by muse, mutect2, varscan2
- ZNF521 | c.-123G>A | 5'UTR (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100833120; called by muse, mutect2, varscan2
